Somatic mutation profile of tumor specimen ALCH-B26X-TTP1-A (aliquot ALCH-B26X-TTP1-A-5-0-D-A76N-36) from ALCHEMIST case ALCH-B26X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.3 years (29,313 days).
Specimen ALCH-B26X-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db177dd3-5641-45e2-a417-31e295e62c01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26X-NB1-A (Blood Derived Normal), aliquot ALCH-B26X-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33ed086c-503c-48d2-8280-0395d5762cf9

The open-access MAF lists 71 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 19, 5'UTR 4, 5'Flank 3, Intron 2, In Frame Del 2, Nonsense Mutation 2, RNA 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1161T>G p.N387K | Missense Mutation (SNP) | VAF 68/314 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62688055, COSV62689041; called by muse, mutect2, varscan2
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 35/137 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 43/356 reads (12%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSA | c.684C>T p.H228= | Splice Region (SNP) | VAF 18/81 reads (22%) | catalogued as rs762695598; called by muse, mutect2, varscan2
- BRWD3 | c.3660C>G p.F1220L | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956490; called by muse, mutect2, varscan2
- CNTFR | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480501630, COSV100667544; called by muse, mutect2
- DNAH10 | c.9979C>T p.R3327W (on ENST00000409039; = p.R3266W on NM_207437.3) | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs749014213; called by muse, mutect2
- EYS | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1400774007; called by muse, mutect2, varscan2
- GREB1 | c.5290G>A p.V1764M | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as rs758464621, COSV52182249; called by muse, mutect2, varscan2
- ITGB8 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.967); catalogued as COSV56011827; called by muse, mutect2, varscan2
- KLHL35 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.034); catalogued as rs1291773911; called by muse, mutect2, varscan2
- LAMC1 | c.3526A>G p.M1176V | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as rs1355636921; called by muse, mutect2, varscan2
- PROK2 | c.365G>A p.R122Q (on ENST00000295619 / NM_001126128.2; = p.R101Q on NM_021935.4) | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs371819884; called by muse, mutect2, varscan2
- RLN1 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1282061560; called by muse, mutect2, varscan2
- SETD2 | c.4686G>T p.W1562C | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100339362, COSV57430727; called by muse, mutect2, varscan2
- SLC32A1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV54147727, COSV99462101; called by muse, mutect2, varscan2
- SMC1A | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59130478; called by muse, mutect2
- TEKT2 | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 132/504 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs1384455091; called by muse, mutect2, varscan2
- ZNF568 | c.520A>T p.S174C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61740725; called by muse, mutect2, varscan2
- ACTR10 | c.325_339del p.L109_F113del | In Frame Del (DEL) | VAF 14/119 reads (12%) | called by mutect2, pindel
- ATF4 | c.862A>G p.N288D | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CFL2 | c.128A>C p.D43A | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CHST9 | c.243C>G p.N81K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- CXXC1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX3X | c.829T>A p.L277M (on ENST00000399959; = p.L278M on NM_001356.5) | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLL4 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJB1 | c.821C>G p.P274R | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ERCC6L | c.3044T>A p.V1015D | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GFM2 | c.1577A>T p.D526V | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); called by muse, varscan2
- GPR143 | c.924G>T p.L308F | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- KHNYN | c.1345A>C p.M449L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NLRP10 | c.992A>G p.E331G | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NT5DC3 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 50/190 reads (26%) | called by muse, varscan2
- SLC22A18 | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 132/471 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SMG1 | c.4316C>T p.S1439F | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2
- TFRC | c.2257G>T p.V753F | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMEM209 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); called by muse, varscan2
- TRIM33 | c.2567G>T p.S856I | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBA1 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 86/287 reads (30%) | called by muse, mutect2, varscan2
- ZNF845 | c.710A>T p.H237L | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ADAMDEC1 | c.1272G>A p.G424= | Silent (SNP) | VAF 11/183 reads (6%) | catalogued as COSV56475167; called by muse, mutect2
- ADGRG4 | c.3063C>A p.G1021= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs1186522562; called by mutect2, varscan2
- CASP14 | c.270G>T p.G90= | Silent (SNP) | VAF 40/161 reads (25%) | catalogued as COSV55665300; called by muse, mutect2, varscan2
- CATSPER1 | c.507C>T p.H169= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as rs779016319, COSV56408823; called by muse, mutect2, varscan2
- CCDC166 | c.1119G>T p.L373= | Silent (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- CCDC180 | c.576C>T p.D192= | Silent (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- DNAH1 | c.10194C>G p.L3398= | Silent (SNP) | VAF 24/404 reads (6%) | called by muse, mutect2
- EIF3D | c.93G>A p.Q31= | Silent (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- FKBP10 | c.561C>T p.D187= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs782502878, COSV58636413; called by muse, mutect2, varscan2
- GALNT18 | c.1734C>T p.S578= | Silent (SNP) | VAF 58/255 reads (23%) | catalogued as rs569322951; called by muse, mutect2, varscan2
- ITGA6 | c.90G>A p.E30= | Silent (SNP) | VAF 67/331 reads (20%) | catalogued as rs1006950275; called by muse, mutect2, varscan2
- ITIH5 | c.2691C>T p.N897= | Silent (SNP) | VAF 30/350 reads (9%) | catalogued as rs767367042, COSV99903860; called by muse, mutect2
- KIR2DL1 | c.696T>A p.T232= | Silent (SNP) | VAF 27/209 reads (13%) | called by muse, mutect2, varscan2
- OSBP2 | c.2070C>T p.I690= | Silent (SNP) | VAF 59/283 reads (21%) | catalogued as rs748469246; called by muse, mutect2, varscan2
- P2RX5 | c.150G>T p.L50= | Silent (SNP) | VAF 47/244 reads (19%) | called by muse, mutect2, varscan2
- RBBP7 | c.699C>G p.A233= | Silent (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- TMC1 | c.933C>T p.F311= | Silent (SNP) | VAF 61/224 reads (27%) | called by muse, mutect2, varscan2
- TRIM65 | c.915C>T p.P305= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs779084029; called by muse, mutect2, varscan2
- ZNF415 | c.336G>A p.T112= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs148927334; called by muse, mutect2, varscan2
- AIP | c.-36C>A | 5'UTR (SNP) | VAF 37/139 reads (27%) | called by muse, mutect2, varscan2
- BAIAP2 | chr17:81032925 A>C | 5'Flank (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2
- C2CD3 | chr11:74171165 G>A | 5'Flank (SNP) | VAF 80/372 reads (22%) | called by muse, mutect2, varscan2
- EGFR | c.1881-814C>T | Intron (SNP) | VAF 198/487 reads (41%) | catalogued as rs1185366027, COSV51846022; called by muse, mutect2, varscan2
- FAM169B | n.429T>A | RNA (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- JMJD8 | c.*865C>T | 3'UTR (SNP) | VAF 26/237 reads (11%) | catalogued as rs756410052; called by muse, mutect2, varscan2
- MAPK15 | c.-14G>T | 5'UTR (SNP) | VAF 52/204 reads (25%) | called by muse, varscan2
- MIEN1 | c.-21G>C | 5'UTR (SNP) | VAF 78/258 reads (30%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:18610207 T>C | 5'Flank (SNP) | VAF 71/589 reads (12%) | catalogued as rs771529537; called by muse, mutect2, varscan2
- NPL | c.231-2879A>G | Intron (SNP) | VAF 6/57 reads (11%) | catalogued as rs1219932377; called by muse, mutect2
- SELENBP1 | c.-30C>T | 5'UTR (SNP) | VAF 51/281 reads (18%) | catalogued as rs375756111; called by muse, mutect2, varscan2
